Somatic mutation profile of tumor specimen 0DOBTA from CCDI case PBBZTM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.4 years (3,058 days).
Specimen 0DOBTA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0424f5c8-eb1f-43a5-aa35-d951dd5b4c2c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOBSO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81620ba7-9659-44f1-a191-6180c452d247

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LAMTOR3 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 14/393 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs1311323942; called by muse, mutect2
- ADAMTS1 | c.1626C>T p.N542= | Silent (SNP) | VAF 170/492 reads (35%) | catalogued as rs146032381; called by muse, mutect2, varscan2
